Gene-level copy-number profile of tumor specimen TCGA-32-4210-01A from TCGA case TCGA-32-4210, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.3 years (26,768 days).
Specimen TCGA-32-4210-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.e8df6c9f-f66c-44ac-9549-7a9c489a8c62.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,151 have no estimate.
https://portal.gdc.cancer.gov/files/78757c1e-e10a-4503-9e9c-e2694e47626f

Most common (modal) total copy number across autosomal genes: 7 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 2; copy number 2: 164; copy number 3: 50; copy number 4: 11,596; copy number 5: 13,721; copy number 6: 7,670; copy number 7: 22,171.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-32-4210-01A-01D-1224-01): tumor purity 0.75, ploidy 5.99, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,058,771–27,529,814, 98 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 15, i.e. more than twice the modal value of 7; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
